TCGA case TCGA-LP-A5U2 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri; Tissue source site: ILSBIO. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1ef20703-3684-4b43-a31f-892073208377

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 30 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, endocervical type: ICD-O-3 morphology code: 8384/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 30.3 years (11,049 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 9 days.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 7; Lymphatic invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS, postoperative.

Follow-up (2 entries)
- Day 6 (preoperative): ECOG performance status: 1.
- Days to follow up: 9 days; Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Induced Abortion.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: Yes.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.
- Timepoint category: Initial Diagnosis; Weight: 51 kg; Height: 160 cm; BMI: 19.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LP-A5U2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 550 mg.
  Slide TCGA-LP-A5U2-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-LP-A5U2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LP-A5U2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Pregnancies count induced abortion: 1; Total pregnancy count: 1; Tobacco smoking history indicator: 1; Days from index date to performance status: 6; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Endocervical Adenocarcinoma of the Usual Type; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent; New tumor event diagnosis indicator: No.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 9 days; disease-specific survival: no event (censored), 9 days; disease-free interval: no event (censored), 9 days; progression-free interval: no event (censored), 9 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-LP-A5U2-01A-11D-A28A-01): tumor purity 0.87, ploidy 2.2, whole-genome doublings 0.
